Somatic mutation profile of tumor specimen C3N-03853-01 (aliquot CPT0237270011) from CPTAC case C3N-03853, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 49.2 years (17,976 days).
Specimen C3N-03853-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0bc252c-200c-41db-b334-1f3ff4bc10e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03853-31 (Blood Derived Normal), aliquot CPT0237330002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b289008e-b14d-4a32-9199-4bd83477f9d0

The open-access MAF lists 54 somatic variants for this specimen: 40 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 8, Nonsense Mutation 4, Frame Shift Del 3, RNA 3, Intron 2, Splice Site 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 70/501 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 126/519 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY6 | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 29/557 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as rs769852411, COSV104410976; called by muse, mutect2
- ANO2 | c.2705G>A p.R902H (on ENST00000356134 / NM_001278597.3; = p.R906H on NM_001278596.3) | Missense Mutation (SNP) | VAF 81/626 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs192113570, COSV59020943; called by muse, mutect2
- CHGB | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 60/374 reads (16%) | catalogued as rs760333741; called by muse, mutect2, varscan2
- DBNL | c.943G>C p.E315Q (on ENST00000448521 / NM_001014436.3; = p.E316Q on NM_014063.7) | Missense Mutation (SNP) | VAF 68/373 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV51977115; called by muse, mutect2, varscan2
- FAT2 | c.9599C>T p.T3200M | Missense Mutation (SNP) | VAF 174/951 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1416807728, COSV55822841; called by muse, mutect2, varscan2
- FBF1 | c.2641C>T p.R881W (on ENST00000586717; = p.R895W on NM_001319193.1) | Missense Mutation (SNP) | VAF 52/394 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1025965803; called by muse, mutect2, varscan2
- IGHV2-5 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 150/911 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as rs782348529; called by muse, mutect2, varscan2
- MEP1B | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 370/607 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs757121510, COSV52496715; called by muse, mutect2, varscan2
- MUC19 | c.424del p.Y142Mfs*99 | Frame Shift Del (DEL) | VAF 15/124 reads (12%) | catalogued as rs776041179; called by mutect2, pindel, varscan2
- NYX | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs778437203, COSV61180564; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PAX8 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 68/1158 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.143); catalogued as rs868276472; called by muse, mutect2
- PHRF1 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 99/557 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as rs749964878; called by muse, mutect2, varscan2
- RYR1 | c.9892G>A p.A3298T | Missense Mutation (SNP) | VAF 108/660 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs544339193, COSV62092810; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC1A3 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 122/1200 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766340486, COSV54314181; called by muse, mutect2, varscan2
- SLIT3 | c.2323C>T p.R775* | Nonsense Mutation (SNP) | VAF 35/287 reads (12%) | catalogued as rs767878241; called by muse, mutect2, varscan2
- SPRN | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 56/378 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1276484296; called by muse, mutect2, varscan2
- SYNGAP1 | c.3184G>A p.G1062R | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.139); catalogued as rs1464015871, COSV99538807; called by muse, mutect2
- TFDP3 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 91/443 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs1239930035, COSV59536633; called by muse, mutect2, varscan2
- TRIM55 | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 29/177 reads (16%) | catalogued as rs750201649, COSV52545400; called by muse, mutect2, varscan2
- WNK2 | c.6421G>A p.A2141T (on ENST00000297954 / NM_001282394.1; = p.A2104T on NM_006648.3) | Missense Mutation (SNP) | VAF 54/287 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs537020225; called by muse, mutect2, varscan2
- ZNF284 | c.544A>T p.K182* | Nonsense Mutation (SNP) | VAF 43/292 reads (15%) | catalogued as rs868833403; called by muse, mutect2, varscan2
- ABRA | c.236dup p.S81Vfs*20 | Frame Shift Ins (INS) | VAF 96/639 reads (15%) | called by mutect2, pindel, varscan2
- ANKRD36 | c.1193G>A p.R398K | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- BRWD3 | c.2546C>G p.S849C | Missense Mutation (SNP) | VAF 44/317 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CACNA1E | c.3922G>A p.V1308I | Missense Mutation (SNP) | VAF 56/375 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- CNKSR1 | c.944_947+11del p.X315_splice (on ENST00000374253 / NM_001297647.2; = p.X308_splice on NM_006314.3) | Splice Site (DEL) | VAF 53/500 reads (11%) | called by mutect2, pindel
- GRIA1 | c.2644G>A p.D882N | Missense Mutation (SNP) | VAF 159/915 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- KCNH8 | c.2860A>G p.I954V | Missense Mutation (SNP) | VAF 86/585 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNT2 | c.2063T>A p.L688H | Missense Mutation (SNP) | VAF 34/345 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- NPR3 | c.553G>C p.G185R | Missense Mutation (SNP) | VAF 40/420 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- NUB1 | c.739_742del p.I247Efs*12 | Frame Shift Del (DEL) | VAF 67/603 reads (11%) | called by pindel, varscan2
- OR1N2 | c.693C>G p.I231M | Missense Mutation (SNP) | VAF 112/503 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- PICALM | c.232T>C p.S78P | Missense Mutation (SNP) | VAF 61/280 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- PTPRD | c.1013G>T p.S338I | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- STAG2 | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2
- TMEM131 | c.3057del p.F1019Lfs*3 | Frame Shift Del (DEL) | VAF 32/266 reads (12%) | called by mutect2, pindel, varscan2
- TMIGD1 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.037); called by muse, mutect2
- ZNF763 | c.796C>G p.H266D (on ENST00000358987 / NM_001367172.2; = p.H269D on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/433 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- MAP3K15 | c.1653C>A p.A551= | Silent (SNP) | VAF 18/179 reads (10%) | catalogued as rs780220344; called by muse, mutect2, varscan2
- SHROOM2 | c.2085G>A p.T695= | Silent (SNP) | VAF 65/440 reads (15%) | catalogued as rs760036869, COSV66608779; called by muse, mutect2, varscan2
- SI | c.3828G>A p.Q1276= | Silent (SNP) | VAF 66/424 reads (16%) | called by muse, mutect2, varscan2
- SOBP | c.2049C>T p.S683= | Silent (SNP) | VAF 42/207 reads (20%) | catalogued as rs945395751; called by muse, mutect2, varscan2
- SYNE1 | c.3897G>A p.A1299= (on ENST00000367255 / NM_182961.4; = p.A1306= on NM_033071.3) | Silent (SNP) | VAF 145/901 reads (16%) | catalogued as COSV55034127; called by muse, mutect2, varscan2
- TMTC1 | c.504G>A p.A168= (on ENST00000539277 / NM_001193451.2; = p.A60= on NM_175861.3) | Silent (SNP) | VAF 55/329 reads (17%) | catalogued as rs769031907, COSV55481117; called by muse, mutect2, varscan2
- TRPM8 | c.819C>T p.V273= | Silent (SNP) | VAF 47/271 reads (17%) | catalogued as rs200501002; called by muse, mutect2, varscan2
- UNC13A | c.2562C>T p.Y854= | Silent (SNP) | VAF 86/613 reads (14%) | catalogued as rs374674567; ClinVar: likely benign; called by muse, mutect2, varscan2
- AC104078.1 | n.153C>T | RNA (SNP) | VAF 88/542 reads (16%) | catalogued as rs1393259791; called by mutect2, varscan2
- GORASP2 | c.63+424C>T | Intron (SNP) | VAF 35/261 reads (13%) | catalogued as rs770400543; called by muse, mutect2, varscan2
- OFCC1 | n.1456C>T | RNA (SNP) | VAF 71/406 reads (17%) | catalogued as rs1218376012; called by muse, mutect2, varscan2
- RGMB | chr5:98770641 ins C | 5'Flank (INS) | VAF 19/91 reads (21%) | catalogued as rs758138739; called by mutect2, pindel, varscan2
- TUBB7P | n.922G>A | RNA (SNP) | VAF 104/698 reads (15%) | catalogued as rs782633351; called by muse, mutect2, varscan2
- ZFHX3 | c.-897+3579A>G | Intron (SNP) | VAF 63/296 reads (21%) | called by mutect2, varscan2
